Gene-level copy-number profile of tumor specimen TCGA-CV-A6JT-01A from TCGA case TCGA-CV-A6JT, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 65.2 years (23,806 days).
Specimen TCGA-CV-A6JT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.045fa1d3-99d8-4924-9ab8-64ac4cec0cfb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-A6JT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/51541514-fe4c-4f66-9f22-3b6da2400905

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 8; copy number 2: 7,402; copy number 3: 1,025; copy number 4: 45,958; copy number 5: 518; copy number 6: 2,883; copy number 7: 1,550; copy number 8: 32; copy number 9: 26; copy number 11: 54; copy number 12: 208; copy number 19: 99; copy number 24: 3; copy number 33: 11; copy number 36: 2; copy number 49: 33; copy number 59: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-A6JT-01A-11D-A31K-01): tumor purity 0.5, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 437 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:50,396,192–60,522,120, 153 genes, copy number 11–59 (within-gene range 4–59) (broad region; genes not listed).
- chr7:2,234,195–3,302,452, 25 genes, copy number 9: MRM2, NUDT1, SNX8, MIR6836, IMMP1LP3, EIF3B, AC004840.1, AC004840.2, CHST12, GRIFIN, LFNG, MIR4648, BRAT1, IQCE, TTYH3, AMZ1, GNA12, AC006028.1, CARD11, CARD11-AS1, RN7SKP130, AC024028.1, AC073316.1, AC073316.2, SDK1-AS1.
- chr7:3,337,889–3,338,601, 1 gene, copy number 9: AC092427.1.
- chr7:38,655,205–55,713,252, 258 genes, copy number 12–49 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
